Somatic mutation profile of tumor specimen TCGA-55-7284-01B (aliquot TCGA-55-7284-01B-11D-2238-08) from TCGA case TCGA-55-7284, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.2 years (27,087 days).
Specimen TCGA-55-7284-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf821435-ea32-4fb4-b0c5-5c3207cb2763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7284-10A (Blood Derived Normal), aliquot TCGA-55-7284-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b248ecb0-657d-4437-9b9e-0a9ce1c46990

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56858893; called by muse, mutect2, varscan2
- C9orf50 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV65252633; called by muse, mutect2, varscan2
- CHAF1A | c.1274A>G p.K425R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100010886; called by muse, mutect2
- CHD5 | c.4508G>A p.R1503H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1191550582, COSV52415523; called by muse, mutect2, varscan2
- ELP4 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100635138; called by muse, mutect2, varscan2
- EPHB2 | c.2932A>T p.M978L (on ENST00000400191 / NM_001309193.2; = p.M979L on NM_004442.7) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.115); catalogued as COSV101006799; called by muse, mutect2
- FAP | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV99501786; called by muse, mutect2, varscan2
- FFAR3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs767171390, COSV59909838; called by muse, mutect2, varscan2
- GPATCH4 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV100576883; called by muse, mutect2, varscan2
- GSX1 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs765237584, COSV100262464, COSV57233400; called by mutect2, varscan2
- GYS1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760668113, COSV99620486; called by muse, varscan2
- HELZ2 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100915455; called by muse, varscan2
- KDM5B | c.516A>T p.R172S | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99350135; called by muse, mutect2, varscan2
- MAP3K4 | c.4211G>A p.R1404Q | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs771133700, COSV100815091; called by muse, mutect2, varscan2
- NCOA5 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.74); catalogued as COSV99275261; called by muse, mutect2, varscan2
- NRXN3 | c.1176G>T p.L392F (on ENST00000335750 / NM_001330195.2; = p.L19F on NM_004796.6) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100201220; called by muse, mutect2, varscan2
- OR2D3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV100505001; called by muse, mutect2, varscan2
- OR5B2 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV100222797; called by muse, mutect2, varscan2
- RASGRF1 | c.1166T>A p.I389N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101369521; called by muse, mutect2, varscan2
- REV3L | c.8185A>T p.N2729Y | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724937; called by muse, mutect2, varscan2
- SLFN5 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs771075051, COSV100249527; called by muse, mutect2, varscan2
- SYT8 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as COSV99062144; called by muse, mutect2, varscan2
- TNR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371035988, COSV54876906; called by muse, mutect2, varscan2
- TTN | c.23200G>A p.D7734N (on ENST00000591111; = p.D6807N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | PolyPhen benign (0.028); catalogued as rs368226720, COSV60066322; called by muse, mutect2, varscan2
- TXNRD1 | c.1598G>A p.C533Y (on ENST00000525566 / NM_001093771.3; = p.C435Y on NM_003330.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100723325; called by muse, mutect2, varscan2
- USH2A | c.7388C>G p.A2463G | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100230019, COSV56353359; called by muse, mutect2, varscan2
- WDR75 | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100134047; called by muse, mutect2, varscan2
- ZNF577 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100030818; called by muse, mutect2, varscan2
- ALDH3A1 | c.675G>A p.L225= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99855751; called by muse, mutect2, varscan2
- BNC1 | c.873T>C p.T291= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as COSV100596944, COSV100597241; called by muse, mutect2
- FBXW7 | c.432G>A p.T144= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1472074824, COSV55893053, COSV99904675; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1449C>T p.V483= | Silent (SNP) | VAF 22/361 reads (6%) | catalogued as rs1050323587, COSV100079419; called by muse, mutect2
- KCTD11 | c.465C>T p.S155= (on ENST00000333751 / NM_001363642.1; = p.S116= on NM_001002914.2) | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as rs764254256, COSV99341457; called by muse, mutect2
- LRRC59 | c.321C>G p.L107= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV99869389; called by muse, mutect2, varscan2
- MEIS1 | c.564C>T p.D188= | Silent (SNP) | VAF 38/221 reads (17%) | catalogued as rs775405225, COSV55483197; called by muse, mutect2, varscan2
- MYOM2 | c.2343C>T p.Y781= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs141326692, COSV50703156; called by muse, mutect2, varscan2
- NGLY1 | c.966T>A p.A322= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99770151; called by muse, mutect2, varscan2
- SDK1 | c.475T>C p.L159= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV67378520; called by muse, mutect2, varscan2
- SPTAN1 | c.7239C>T p.F2413= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as COSV100823212; called by muse, mutect2, varscan2
- UPK2 | c.495C>T p.V165= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs776578281, COSV50629061; called by muse, mutect2, varscan2
- MACF1 | c.15832-8062G>T | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs374619525; called by muse, mutect2, varscan2
